Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A1KQ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A1KQ-01A (Primary Tumor).

[page 1 of 4]
Clinical Diagnosis & History:

y/o male with left breast cancer (invasive ductal carcinoma (IDC)).

Specimens Submitted:

- 1: SP: Sentinel node #1, level 1, left axilla (fs)
- 2: SP: Left breast with levels one and two axillary contents

DIAGNOSIS:

- 1) LYMPH NODE, LEFT AXILLA, SENTINEL LYMPH NODE #1; LEVEL 1; BIOPSY:
- METASTATIC CARCINOMA IN ONE LYMPH NODE (1/1).
- THE METASTATIC DEPOSIT IS SEEN ONLY ON THE ACTUAL FROZEN SECTION AND MEASURES AT LEAST 2 MM. NO EXTRANODAL EXTENSION IDENTIFIED.
- THE LYMPH NODE EXHIBITS INCIDENTAL BENIGN CAPSULAR NEVUS CELL AGGREGATES.
- 2) BREAST, LEFT, MASTECTOMY:
- INVASIVE DUCTAL CARCINOMA, NOS TYPE, HISTOLOGIC GRADE III/III (SLIGHT OR NO TUBULE FORMATION), NUCLEAR GRADE III/III (MARKED VARIATION IN SIZE AND SHAPE), MEASURING 2.2 CM IN LARGEST DIMENSION MICROSCOPICALLY.
- DUCTAL CARCINOMA IN-SITU (DCIS) IS ALSO IDENTIFIED, SOLID, CRIBRIFORM TYPE WITH HIGH NUCLEAR GRADE AND MODERATE NECROSIS.
- THE DCIS CONSTITUTES <= 25% OF THE TOTAL TUMOR MASS, AND IS PRESENT ADMIXED WITH AND AWAY FROM THE INVASIVE COMPONENT.
- THE INVASIVE CARCINOMA IS LOCATED IN THE LOWER INNER QUADRANT AND CENTRAL AREA (RETROAREOLAR).
- THE NIPPLE IS INVOLVED BY INVASIVE CARCINOMA.
- A FOCUS OF PERINEURAL INVASION BY CARCINOMA IS SEEN IN THE DERMIS OF THE NIPPLE REGION. THERE IS ALSO FOCAL LYMPHATIC INVASION IN THE NIPPLE REGION.
- CALCIFICATIONS ARE PRESENT IN THE IN SITU CARCINOMA.
- NO INVOLVEMENT OF THE SURGICAL MARGINS BY EITHER INVASIVE OR IN SITU CARCINOMA IS IDENTIFIED.
- THE NON-NEOPLASTIC BREAST TISSUE IS UNREMARKABLE.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF POSITIVE LYMPH NODES IN RELATION TO THE TOTAL NUMBER OF LYMPH NODES EXAMINED):-- METASTATIC CARCINOMA IN ONE OF EIGHT LYMPH NODES (1/8).
- THIS IS A MACROMETASTASIS (1.8 CM).
- THERE IS NO EXTRANODAL EXTENSION OF CARCINOMA.

** Continued on next page **

ICD-0-3

Carcinoma, infiltrating ductal, NOS 8500/3
Site breast, NOS C50.9 3/16/11
lw

[page 2 of 4]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	ER-C	
	PR-C	
	HER2-C	
	NEG CONT	
	NEG-HER2	
	IMM RECUT	

Gross Description:

1). The specimen is received fresh for frozen section consultation labeled,
"Sentinel node #1, level 1, left axilla", and consists of one lymph node
measuring 1.5 x 1.0 x 0.8 cm. The lymph node is bisected and submitted for
frozen section diagnosis.

Summary sections:

FSC - frozen section control

2). The specimen is received fresh labeled, "Left breast with levels one and
two axillary contents, stitch marks axillary tail" and consists of a breast
measuring 19 x 18 x 3.5 cm with overlying skin ellipse measuring 19 x 11 cm,
attached axillary contents measuring 11 x 10 x 3 cm. The axillary tail is
marked with a black suture. Situated centrally on the skin surface is a
flattened nipple measuring 0.8 x 0.8 cm and areola measuring 2.5 x 2.5 cm.
There are no scars or lesions noted on the skin. A suture demarcates the
axillary aspect. The posterior surface of the breast is inked black and the
specimen is serially sectioned to reveal a well circumscribed stony hard
white-tan tumor measuring 2.0 x 2.0 x 1.7 cm, and located 1.8 cm from the
deep margin. The tumor is located subjacent to the nipple. The remainder of
the breast tissue is yellow tan fatty and lobulated. The specimen is
submitted for lymph node dissection. Representative sections are submitted.
A sample of the tumor is given to

Summary of sections:

N nipple

** Continued on next page **

[page 3 of 4]
NB - nipple base
DM - deep margin
T - tumor
UIQ - upper inner quadrant
LIQ - lower inner quadrant
UOQ - upper outer quadrant
LOQ - lower outer quadrant
LN-lymph nodes

Summary of Sections:

Part 1: SP: Sentinel node #1, level 1, left axilla (fs)

Block	Sect.	Site	PCs
1	FSC		1

Part 2: SP: Left breast with levels one and two axillary contents

Block	Sect.	Site	PCs
1	dm		1
1	liq		1
5	LN		8
1	loq		1
1	n		1
1	nb		1
6	t		6
1	uiq		1
1	uoq		1

Procedures/Addenda:

Addendum

Date Ordered:	Status: Signed Out
Date Complete:	By:
Date Reported:	

Addendum Diagnosis

ADDEN----

SITE: #2, LEFT BREAST

- ER: >95% OF NUCLEAR STAINING WITH STRONG INTENSITY.
- PR: >80% OF NUCLEAR STAINING WITH STRONG TO MODERATE INTENSITY.
- HER-2/NEU
(Hercep Test): NEGATIVE (STAINING INTENSITY OF FOCAL 1+).
- CONTROLS ARE SATISFACTORY.

** Continued on next page **

[page 4 of 4]
Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: METASTATIC CARCINOMA
PERMANENT DIAGNOSIS: SAME.

** End of Report **

Source: NCI Genomic Data Commons file 2df5bcec-b6d7-4a8c-b83d-15453698b0cb (TCGA-AO-A1KQ.EB5199BA-6164-4CFB-AFAA-B41544B83103.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).